Somatic mutation profile of tumor specimen TCGA-09-0366-01A (aliquot TCGA-09-0366-01A-01W-0372-09) from TCGA case TCGA-09-0366, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.0 years (20,440 days).
Specimen TCGA-09-0366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f151f857-8d35-4aac-8a87-9bb0abde98ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0366-10B (Blood Derived Normal), aliquot TCGA-09-0366-10B-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cb1a524-8b0a-4d47-b2ca-379045fb5225

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 68/93 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51474244; called by muse, mutect2, varscan2
- ADCY1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV52030815; called by muse, mutect2, varscan2
- APH1A | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 108/527 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52528259, COSV52528319; called by muse, mutect2, varscan2
- CDH3 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs369109043; called by muse, mutect2, varscan2
- COL7A1 | c.3765G>T p.Q1255H | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV60391872, COSV60401076; called by muse, mutect2, varscan2
- CPSF2 | c.2305T>G p.Y769D | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54097221; called by muse, mutect2, varscan2
- DLGAP4 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV59414932; called by muse, mutect2, varscan2
- GPR149 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs906925874, COSV67666015; called by muse, mutect2, varscan2
- GPR158 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100893598; called by muse, mutect2
- HIPK2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs780228518, COSV61226012; called by muse, mutect2, varscan2
- HRH4 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 104/446 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as rs889005723, COSV56927444; called by muse, mutect2, varscan2
- IFT20 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs1247390444; called by muse, mutect2, varscan2
- LGI1 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as COSV65057518; called by muse, mutect2, varscan2
- LRRC46 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs940952448, COSV51635060; called by muse, mutect2, varscan2
- LRRC49 | c.767T>G p.I256R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53008357; called by muse, mutect2, varscan2
- MAST3 | c.2290T>A p.S764T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV53217939; called by muse, mutect2, varscan2
- MBTPS2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs764955640, COSV63410842; called by muse, mutect2, varscan2
- NDUFAF1 | c.670A>C p.K224Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV52974812; called by muse, mutect2, varscan2
- PIKFYVE | c.222G>C p.W74C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV52237648; called by muse, mutect2, varscan2
- PLXNB1 | c.4569G>T p.K1523N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56487063; called by muse, mutect2, varscan2
- PPP1R3A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV52877440; called by muse, mutect2, varscan2
- PRAMEF4 | c.343T>C p.W115R | Missense Mutation (SNP) | VAF 275/1359 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52437456; called by muse, mutect2, varscan2
- RGS21 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314018, COSV69881457; called by muse, mutect2
- SPACA3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV52190498; called by muse, mutect2, varscan2
- SPAG5 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as rs1171612198, COSV58803718; called by muse, mutect2
- THSD1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs564794340, COSV51628509, COSV51631698; called by muse, mutect2, varscan2
- THSD7A | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 45/214 reads (21%) | catalogued as COSV70260927; called by muse, mutect2, varscan2
- UBR4 | c.4124C>T p.S1375F | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100922031; called by muse, mutect2
- UTRN | c.3767T>G p.M1256R | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV62329350; called by muse, mutect2, varscan2
- ZFYVE9 | c.4215C>G p.C1405W | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55090623, COSV55098318; called by muse, mutect2, varscan2
- BRWD1 | c.5520G>T p.M1840I | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- C1orf54 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CC2D2B | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- COL4A3 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- COPS5 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- EIF4ENIF1 | c.2669del p.G890Efs*89 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | called by mutect2, pindel, varscan2
- GLRA3 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- IHO1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- KDM5A | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.138); called by muse, mutect2
- MCF2L2 | c.3013A>T p.K1005* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- NID1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PCARE | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PHRF1 | c.1137A>C p.R379S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PLOD3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PODXL | c.1554del p.S519Lfs*27 (on ENST00000378555 / NM_001018111.3; = p.S487Lfs*27 on NM_005397.4) | Frame Shift Del (DEL) | VAF 37/345 reads (11%) | called by mutect2, pindel, varscan2
- PRTG | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SUN1 | c.560_568del p.N187_S189del (on ENST00000405266 / NM_001367651.1; = p.N137_S139del on NM_025154.6 and 13 other RefSeq transcripts) | In Frame Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- TINF2 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 12/423 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); called by muse, mutect2
- XIAP | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ZNF318 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- ARR3 | c.438C>T p.F146= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV57203183; called by muse, mutect2, varscan2
- CDK9 | c.855C>T p.D285= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- COL7A1 | c.1428G>A p.P476= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs138330564; called by muse, mutect2, varscan2
- ENO1 | c.999C>T p.N333= | Silent (SNP) | VAF 82/428 reads (19%) | catalogued as rs146867004; called by muse, mutect2, varscan2
- HS3ST2 | c.633C>T p.A211= | Silent (SNP) | VAF 95/452 reads (21%) | catalogued as rs768326313, COSV54458793; called by muse, mutect2, varscan2
- LIPC | c.133C>T p.L45= | Silent (SNP) | VAF 302/573 reads (53%) | catalogued as rs374220111; called by muse, mutect2, varscan2
- MCTP2 | c.1330C>T p.L444= | Silent (SNP) | VAF 11/247 reads (4%) | called by muse, mutect2
- MPP6 | c.546G>A p.E182= | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as COSV99757692; called by muse, mutect2
- MYO7A | c.1071C>G p.S357= | Silent (SNP) | VAF 899/910 reads (99%) | catalogued as COSV101289093, COSV68683668; called by muse, mutect2, varscan2
- OLFML2B | c.180G>A p.L60= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as rs1196905768; called by muse, mutect2, varscan2
- OR7C1 | c.903G>A p.L301= | Silent (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- RNF111 | c.433C>T p.L145= | Silent (SNP) | VAF 10/320 reads (3%) | catalogued as rs1490854929; called by muse, mutect2
- SLC2A9 | c.474G>A p.S158= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs559926779, COSV53317234; called by muse, mutect2, varscan2
- SZT2 | c.2916G>A p.P972= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV65167631; called by muse, mutect2, varscan2
- TTI1 | c.1428C>T p.F476= | Silent (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- ADAMTS20 | c.4284+1634G>C | Intron (SNP) | VAF 7/12 reads (58%) | catalogued as COSV67127573; called by muse, mutect2, varscan2
